Somatic mutation profile of tumor specimen ALCH-B1J8-TTP1-A (aliquot ALCH-B1J8-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1J8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 72.4 years (26,432 days).
Specimen ALCH-B1J8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8226262-5993-4a8f-822d-15d112f4ea62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1J8-NB1-A (Blood Derived Normal), aliquot ALCH-B1J8-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8efa7c69-1466-48b2-88d8-8a179d448fef

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Splice Region 1, 3'Flank 1, Nonsense Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOT | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV100495138, COSV59066769; called by muse, mutect2
- FAT3 | c.4744G>A p.G1582R | Missense Mutation (SNP) | VAF 42/706 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306697026; called by muse, mutect2
- MAP3K11 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV100482212; called by muse, mutect2
- SHROOM3 | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs775566043, COSV56029599; called by muse, mutect2
- ARMC4 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- CCDC168 | c.9178A>G p.N3060D | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.065); called by muse, mutect2
- CEP350 | c.6479G>C p.G2160A | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.039); called by muse, mutect2
- CPA2 | c.384+2T>A p.X128_splice | Splice Site (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- GSTM2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 9/308 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- OR5H2 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 32/466 reads (7%) | called by muse, mutect2
- PJA1 | c.1231G>T p.A411S (on ENST00000361478 / NM_145119.4; = p.A223S on NM_022368.5) | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SETDB1 | c.3669+3G>C | Splice Region (SNP) | VAF 20/517 reads (4%) | called by muse, mutect2
- SHROOM3 | c.3420C>G p.S1140R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- SPDL1 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- THBS3 | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRO | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.207); called by muse, mutect2
- CLCN1 | c.1146C>T p.L382= | Silent (SNP) | VAF 19/537 reads (4%) | called by muse, mutect2
- MINDY4 | c.1569C>T p.F523= | Silent (SNP) | VAF 11/368 reads (3%) | catalogued as COSV54677165; called by muse, mutect2
- OR10J3 | c.348C>T p.L116= | Silent (SNP) | VAF 14/298 reads (5%) | catalogued as COSV59954507; called by muse, mutect2
- PROKR2 | c.159G>A p.K53= | Silent (SNP) | VAF 18/510 reads (4%) | catalogued as COSV54087934; called by muse, mutect2
- TEX13C | c.2742T>C p.D914= | Silent (SNP) | VAF 9/246 reads (4%) | catalogued as rs1464727773; called by muse, mutect2
- CHCHD2P9 | n.346T>C | RNA (SNP) | VAF 28/512 reads (5%) | called by muse, mutect2
- MKRN2OS | chr3:12539174 T>C | 3'Flank (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
